Surgical pathology report (de-identified scan), TCGA case TCGA-SO-A8JP, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Minnesota, specimen TCGA-SO-A8JP-01A (Primary Tumor).

[page 1 of 2]
Normal Blood ID:

SPECIMEN(S):

Left testicle

FINAL DIAGNOSIS:

Testicle, left, radical orchiectomy:

- Histologic type: Seminoma, classical, pure.

- Intratubular germ cell neoplasia: Present

- Extent of invasion:

1. Invasion or penetration of tunica albuginea: Absent
2. Invasion of tunica vaginalis: Absent
3. Involvement of paratesticular structures (epididymis or cord): Absent
4. Angiolymphatic invasion: Absent

- Resection margins (including spermatic cord): All margins negative.

- Lymph nodes: Not included in specimen.

COMMENT:

Sections of the tumor show a classical seminoma; it does not extend through the tunica albuginea. The adjacent testicular tissue shows intratubular germ cell neoplasia, hypospermatogenesis and maturation arrest. There is no evidence of vascular invasion.

CLINICAL HISTORY:

The patient is a -year-old male with left testicle mass.

ICD-O-3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
2011/2/14

[page 2 of 2]
GROSS:

One formalin-filled container is received labeled with the patient's name, medical record number.

The container is labeled "left testicle." The specimen consists of a 5.8 x 4.9 x 3.4 cm, 64.0 gm left orchiectomy specimen with attached 10.0 cm in length and 1.2 cm in diameter segment of spermatic cord. The resection margins are inked. Serial sectioning along the long axis of the testicle demonstrates a 4.4 x 4.3 x 3.2 cm mixed pink-tan and dark red circumscribed tumor with focal areas of hemorrhage. The tumor is 11.0 cm from the closest spermatic cord resection margin, 0.2 cm from the tunica vaginalis margin and 0.4 cm from the epididymis. The tumor occupies 70% of total testicle volume. Representative tissue was procured for potential future studies. Representative sections are submitted in twelve cassettes.

Summary of sections:

- 1 - distal spermatic cord resection margin.
- 2 - closest tunica vaginalis margin.
- 3 - epididymis.
- 4 - intersection between the proximal spermatic cord and tumor.
- 5 through 10 - tumor.
- 11 - normal testicle parenchyma.
- 12 - representative section of spermatic cord at middle and distal segment.

MICROSCOPIC:

Microscopic evaluation is performed.

Agagnosis Discrepancy		✓
PAA Discrepancy		✓
For Malignancy History		✓
Reviewer Initials	BT#	Date Reviewed: 10/25/13

Source: NCI Genomic Data Commons file 5b6a14b2-65b9-41f3-a0a4-50fc941ed787 (TCGA-SO-A8JP.76748130-E97C-4E3A-A1F5-56BC768886E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).